Gene-level copy-number profile of tumor specimen TCGA-AG-A011-01A from TCGA case TCGA-AG-A011, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.7 years (29,463 days).
Specimen TCGA-AG-A011-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.84ad974a-e2a1-4dfc-bb76-d3179bb12397.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A011-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 398 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/046667fc-97f3-4850-9666-20b7d4240bb8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,384; copy number 1: 13,594; copy number 2: 36,955; copy number 3: 6,178; copy number 4: 1,044; copy number 5: 50; copy number 6: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-A011-01A-01D-A003-01): tumor purity 0.55, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr6:147,158,925–147,180,992, 1 gene (within-gene range 0–1): LUADT1.
- chr18:75,407,012–75,427,703, 2 genes: AC116003.1, SMIM21.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 70 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:82,033,533–82,961,926, 4 genes, copy number 5 (within-gene range 4–5): AC060765.2, LINC02839, HNRNPA1P4, AC060765.1.
- chr8:93,213,302–93,700,433, 1 gene, copy number 6 (within-gene range 4–6): LINC00535.
- chr8:93,441,277–94,104,322, 19 genes, copy number 6: RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1.
- chr8:118,976,513–121,641,440, 35 genes, copy number 5: RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2.
- chr8:121,668,934–121,697,600, 1 gene, copy number 5: LINC02855.
- chr8:140,505,813–141,002,216, 10 genes, copy number 5 (within-gene range 4–5): AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278.

Autosomal genes at a single copy (total copy number 1): 13,593. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
